FM case AD2798 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/a04644de-a779-4b89-9aba-55e7305bd9e5

Female, 60.9 years: Serous carcinoma, NOS (ICD-O-3 8441/3) of the ovary; primary biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
